Gene-level copy-number profile of tumor specimen TCGA-CG-4472-01A from TCGA case TCGA-CG-4472, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.6 years (18,110 days).
Specimen TCGA-CG-4472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.331ed964-2a8e-4ee1-aecd-abec0804e59e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4472-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/004c88cd-4754-496e-8460-b85455e271c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5,058; copy number 2: 32,614; copy number 3: 14,715; copy number 4: 6,557; copy number 5: 312; copy number 6: 72; copy number 7: 59; copy number 9: 130; copy number 10: 22; copy number 11: 219; copy number 29: 28; copy number 47: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CG-4472-01): tumor purity 0.5, ploidy 2.54, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:147,660,703–147,953,937, 1 gene (within-gene range 0–1): AL033504.1.
- chr6:162,568,379–162,569,728, 1 gene: KRT8P44.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 871 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,795,300–212,819,264, 1 gene, copy number 6 (within-gene range 4–6): LINC01878.
- chr2:213,284,379–228,379,773, 278 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:183,613,620–188,154,057, 132 genes, copy number 5 (broad region; genes not listed).
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr5:52,787,916–52,959,209, 1 gene, copy number 10 (within-gene range 3–10): ITGA1.
- chr5:52,889,666–53,487,134, 12 genes, copy number 10: B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST.
- chr7:81,946,444–82,443,777, 1 gene, copy number 7 (within-gene range 2–7): CACNA2D1.
- chr7:82,589,848–89,754,726, 61 genes, copy number 7–11 (broad region; genes not listed).
- chr7:90,466,424–91,210,590, 1 gene, copy number 11 (within-gene range 2–11): CDK14.
- chr7:90,590,619–99,419,616, 154 genes, copy number 11 (broad region; genes not listed).
- chr7:99,966,720–100,797,797, 65 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr7:101,154,456–101,224,190, 9 genes, copy number 10: AP1S1, MIR4653, VGF, NAT16, MOGAT3, DGAT2L7P, RPSAP46, PLOD3, ZNHIT1.
- chr7:104,328,700–106,908,980, 42 genes, copy number 11 (within-gene range 2–11): LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG.
- chr12:24,902,309–27,824,382, 76 genes, copy number 7–47 (broad region; genes not listed).
- chr18:20,946,906–22,228,029, 37 genes, copy number 6: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2.

Autosomal genes at a single copy (total copy number 1): 2,639. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
